Somatic mutation profile of tumor specimen C3L-01838-03 (aliquot CPT0091820009) from CPTAC case C3L-01838, project CPTAC-3 (Bronchus and lung — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G2; Age at diagnosis: 70.3 years (25,663 days).
Specimen C3L-01838-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f4370d6b-5439-4bd4-b8e2-dd0773c13a2e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-01838-31 (Blood Derived Normal), aliquot CPT0093670002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/09478e26-09f3-4c00-b7c2-f49997b86800

The open-access MAF lists 137 somatic variants for this specimen: 93 protein-altering or splice-affecting, 25 silent, 19 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 85, Silent 25, Intron 9, 3'UTR 4, Nonsense Mutation 4, 5'UTR 3, 5'Flank 2, Frame Shift Del 2, Splice Site 1, In Frame Del 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.584T>C p.I195T | Missense Mutation (SNP) | VAF 103/617 reads (17%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs760043106, CM092575, COSV52661172, COSV52664264, COSV52684176, COSV52720899; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AP5B1 | c.1733G>T p.R578L | Missense Mutation (SNP) | VAF 12/140 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.07); catalogued as rs376122863, COSV57503073; called by muse, mutect2
- CCDC102A | c.1330C>T p.R444W | Missense Mutation (SNP) | VAF 49/365 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs368027516; called by muse, mutect2, varscan2
- CHD2 | c.569G>A p.R190H | Missense Mutation (SNP) | VAF 20/180 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.026); catalogued as rs776934265, COSV59121024; called by muse, mutect2, varscan2
- DCHS1 | c.4918G>A p.A1640T | Missense Mutation (SNP) | VAF 58/502 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV55040417; called by mutect2, varscan2
- DGKB | c.2168C>A p.A723D | Missense Mutation (SNP) | VAF 32/230 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV99339979; called by muse, mutect2, varscan2
- ESRRA | c.1182A>C p.K394N | Missense Mutation (SNP) | VAF 14/148 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.945); catalogued as COSV50007931; called by muse, mutect2
- FXR2 | c.553G>A p.E185K | Missense Mutation (SNP) | VAF 8/174 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.722); catalogued as COSV51519900; called by muse, mutect2
- GALNTL6 | c.377G>A p.R126H | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV101487914; called by muse, mutect2, varscan2
- HMOX2 | c.259C>T p.R87C | Missense Mutation (SNP) | VAF 36/258 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs147603390; called by muse, mutect2, varscan2
- IFITM5 | c.385G>C p.A129P | Missense Mutation (SNP) | VAF 29/267 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs375637552; called by muse, mutect2, varscan2
- IGKV2-28 | c.104C>A p.P35H | Missense Mutation (SNP) | VAF 22/420 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.125); catalogued as rs1477589594; called by muse, mutect2
- KCNH8 | c.1739G>A p.R580H | Missense Mutation (SNP) | VAF 50/412 reads (12%) | SIFT tolerated (0.51); PolyPhen benign (0.392); catalogued as rs755150313, COSV60457980; called by muse, varscan2
- LMAN1 | c.1469T>C p.V490A | Missense Mutation (SNP) | VAF 65/491 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.005); catalogued as rs1229100365; called by muse, mutect2, varscan2
- MAGEB6 | c.680G>C p.R227T | Missense Mutation (SNP) | VAF 28/88 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.428); catalogued as COSV66872010, COSV66872099; called by muse, mutect2, varscan2
- MAP2 | c.4007C>T p.A1336V | Missense Mutation (SNP) | VAF 26/172 reads (15%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0.027); catalogued as COSV99561863; called by muse, varscan2
- MMP11 | c.940G>T p.G314C | Missense Mutation (SNP) | VAF 116/469 reads (25%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.956); catalogued as rs1456021715; called by muse, mutect2, varscan2
- NIPA1 | c.842G>T p.R281L | Missense Mutation (SNP) | VAF 34/314 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.777); catalogued as CM123611; called by mutect2, varscan2
- NPY1R | c.881C>A p.A294D | Missense Mutation (SNP) | VAF 21/342 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.171); catalogued as COSV56715681; called by muse, mutect2
- OR10G8 | c.26C>G p.A9G | Missense Mutation (SNP) | VAF 26/207 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.109); catalogued as COSV70908207; called by muse, mutect2, varscan2
- OR2M7 | c.425G>T p.G142V | Missense Mutation (SNP) | VAF 40/472 reads (8%) | SIFT tolerated (0.26); PolyPhen benign (0.029); catalogued as COSV58738236, COSV58739311; called by muse, mutect2
- OR51S1 | c.643G>T p.G215C | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.89); catalogued as COSV59059034; called by muse, mutect2, varscan2
- RDH11 | c.155G>T p.G52V | Missense Mutation (SNP) | VAF 17/213 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67282693; called by muse, mutect2
- SLC16A4 | c.1345T>C p.Y449H | Missense Mutation (SNP) | VAF 23/189 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.29); catalogued as rs756066555; called by muse, mutect2, varscan2
- SLC9A4 | c.2038G>A p.D680N | Missense Mutation (SNP) | VAF 42/310 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.048); catalogued as rs776400447; called by muse, varscan2
- THRA | c.115A>G p.M39V | Missense Mutation (SNP) | VAF 60/281 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs1192751220; called by muse, mutect2, varscan2
- TNKS | c.3648A>T p.E1216D | Missense Mutation (SNP) | VAF 25/206 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.817); catalogued as rs754305452; called by muse, mutect2, varscan2
- VANGL2 | c.1012C>G p.H338D | Missense Mutation (SNP) | VAF 16/453 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV63605483; called by muse, mutect2
- ZNF521 | c.2120A>T p.D707V | Missense Mutation (SNP) | VAF 59/443 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64133086; called by muse, mutect2, varscan2
- ABCC2 | c.3246C>A p.N1082K | Missense Mutation (SNP) | VAF 69/534 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ADAM29 | c.1563C>A p.Y521* | Nonsense Mutation (SNP) | VAF 14/184 reads (8%) | called by muse, mutect2
- ADCK1 | c.835A>T p.R279W | Missense Mutation (SNP) | VAF 14/230 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.708); called by muse, mutect2
- AFF1 | c.2858G>T p.G953V | Missense Mutation (SNP) | VAF 27/254 reads (11%) | SIFT tolerated (0.29); PolyPhen benign (0.435); called by muse, varscan2
- AFG3L2 | c.2149A>T p.T717S | Missense Mutation (SNP) | VAF 39/441 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.023); called by muse, mutect2
- ANO10 | c.1333del p.Q445Kfs*19 | Frame Shift Del (DEL) | VAF 46/359 reads (13%) | called by mutect2, pindel, varscan2
- ASAP1 | c.909+1G>C p.X303_splice | Splice Site (SNP) | VAF 80/279 reads (29%) | called by muse, mutect2, varscan2
- AUTS2 | c.1882T>A p.L628I | Missense Mutation (SNP) | VAF 38/276 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.284); called by muse, mutect2, varscan2
- C16orf87 | c.416C>T p.A139V | Missense Mutation (SNP) | VAF 22/271 reads (8%) | SIFT tolerated (0.66); PolyPhen probably damaging (0.968); called by muse, mutect2
- CCDC33 | c.967_980del p.K323Efs*23 | Frame Shift Del (DEL) | VAF 5/67 reads (7%) | called by mutect2, pindel
- CDR1 | c.10T>A p.L4M | Missense Mutation (SNP) | VAF 7/86 reads (8%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.982); called by muse, mutect2
- CHD3 | c.2032C>T p.Q678* | Nonsense Mutation (SNP) | VAF 21/210 reads (10%) | called by muse, mutect2
- CHST10 | c.541A>G p.T181A | Missense Mutation (SNP) | VAF 10/118 reads (8%) | SIFT tolerated (0.22); PolyPhen benign (0.007); called by muse, mutect2
- CLEC2L | c.638A>T p.Y213F | Missense Mutation (SNP) | VAF 24/200 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- COL13A1 | c.250A>G p.M84V | Missense Mutation (SNP) | VAF 20/480 reads (4%) | SIFT tolerated, low confidence (0.17); PolyPhen possibly damaging (0.448); called by muse, mutect2
- COL1A2 | c.1690G>T p.A564S | Missense Mutation (SNP) | VAF 69/491 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- COL9A1 | c.199A>G p.K67E | Missense Mutation (SNP) | VAF 70/488 reads (14%) | SIFT tolerated (0.44); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- DNAAF6 | c.292G>T p.A98S | Missense Mutation (SNP) | VAF 7/121 reads (6%) | SIFT tolerated (0.57); PolyPhen benign (0.034); called by muse, mutect2
- DNAH1 | c.3706G>T p.E1236* | Nonsense Mutation (SNP) | VAF 24/161 reads (15%) | called by muse, mutect2, varscan2
- DNAH7 | c.3985C>T p.P1329S | Missense Mutation (SNP) | VAF 35/215 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DPP7 | c.581G>A p.G194D | Missense Mutation (SNP) | VAF 14/95 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.298); called by muse, mutect2, varscan2
- ETAA1 | c.1103A>T p.N368I | Missense Mutation (SNP) | VAF 32/186 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.468); called by muse, mutect2, varscan2
- FBXO44 | c.207G>C p.K69N | Missense Mutation (SNP) | VAF 15/264 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- FSIP2 | c.9317C>A p.P3106Q | Missense Mutation (SNP) | VAF 31/203 reads (15%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- GLUD1 | c.226C>G p.R76G | Missense Mutation (SNP) | VAF 28/804 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.228); called by muse, mutect2
- IL20RA | c.1435C>G p.L479V | Missense Mutation (SNP) | VAF 17/120 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- INPP5A | c.1061C>T p.S354F | Missense Mutation (SNP) | VAF 41/333 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); called by muse, mutect2, varscan2
- KDM5A | c.311C>T p.T104I | Missense Mutation (SNP) | VAF 64/694 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.076); called by muse, mutect2
- KMT5B | c.2501G>T p.G834V | Missense Mutation (SNP) | VAF 15/191 reads (8%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.586); called by muse, mutect2
- LAMC1 | c.3469G>T p.V1157F | Missense Mutation (SNP) | VAF 40/255 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- LHX8 | c.25G>T p.G9W | Missense Mutation (SNP) | VAF 38/370 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- MARCO | c.1031C>G p.A344G | Missense Mutation (SNP) | VAF 35/263 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- MET | c.2918C>T p.A973V | Missense Mutation (SNP) | VAF 64/596 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- MLLT1 | c.1561C>A p.L521M | Missense Mutation (SNP) | VAF 18/208 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- MYH7 | c.4624_4644del p.S1542_E1548del | In Frame Del (DEL) | VAF 72/775 reads (9%) | called by mutect2, pindel
- MYO5A | c.3824G>T p.S1275I | Missense Mutation (SNP) | VAF 70/645 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.359); called by muse, mutect2, varscan2
- NCKAP5 | c.2139A>T p.L713F | Missense Mutation (SNP) | VAF 20/166 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.483); called by muse, mutect2, varscan2
- NCOR2 | c.7052A>G p.Y2351C | Missense Mutation (SNP) | VAF 60/413 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- NKX3-2 | c.718G>T p.A240S | Missense Mutation (SNP) | VAF 16/160 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NOX4 | c.323G>T p.C108F | Missense Mutation (SNP) | VAF 17/240 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.394); called by muse, mutect2
- PLXNA1 | c.648C>G p.F216L | Missense Mutation (SNP) | VAF 69/531 reads (13%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.868); called by muse, mutect2, varscan2
- PPP4R2 | c.552G>T p.L184F | Missense Mutation (SNP) | VAF 34/224 reads (15%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.986); called by mutect2, varscan2
- PRMT8 | c.885C>A p.C295* | Nonsense Mutation (SNP) | VAF 59/314 reads (19%) | called by muse, mutect2, varscan2
- PRRC2A | c.4682G>T p.R1561L | Missense Mutation (SNP) | VAF 41/308 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- PUS3 | c.284A>T p.E95V | Missense Mutation (SNP) | VAF 27/385 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.02); called by muse, mutect2
- RANBP2 | c.6557A>G p.N2186S | Missense Mutation (SNP) | VAF 60/760 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.239); called by muse, mutect2, varscan2
- RBM43 | c.4G>T p.A2S | Missense Mutation (SNP) | VAF 34/261 reads (13%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.977); called by muse, varscan2
- RIMS1 | c.3032A>T p.Q1011L | Missense Mutation (SNP) | VAF 28/198 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.795); called by muse, mutect2, varscan2
- RTL1 | c.945G>T p.L315F | Missense Mutation (SNP) | VAF 22/273 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- RUNX1T1 | c.981C>G p.N327K (on ENST00000265814 / NM_001198628.1; = p.N300K on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/166 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.001); called by mutect2, varscan2
- RXFP3 | c.90C>G p.D30E | Missense Mutation (SNP) | VAF 5/58 reads (9%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.001); called by muse, mutect2
- SAMD4B | c.1587G>T p.K529N | Missense Mutation (SNP) | VAF 32/295 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- SI | c.3769T>G p.Y1257D | Missense Mutation (SNP) | VAF 76/498 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- SUPT20HL1 | c.2551G>A p.V851M | Missense Mutation (SNP) | VAF 37/200 reads (19%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- TICAM1 | c.895A>T p.N299Y | Missense Mutation (SNP) | VAF 25/237 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- TNFRSF4 | c.323G>T p.R108L | Missense Mutation (SNP) | VAF 20/200 reads (10%) | SIFT tolerated (0.37); PolyPhen benign (0.012); called by muse, mutect2
- TNRC18 | c.6809G>T p.G2270V | Missense Mutation (SNP) | VAF 24/219 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TPM3 | c.424A>G p.M142V | Missense Mutation (SNP) | VAF 57/603 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.043); called by muse, mutect2
- TRHDE | c.2496G>T p.Q832H | Missense Mutation (SNP) | VAF 19/227 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.876); called by muse, mutect2
- TRPA1 | c.916G>C p.D306H | Missense Mutation (SNP) | VAF 124/492 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- TTN | c.16376T>C p.I5459T (on ENST00000591111; = p.I4532T on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 49/364 reads (13%) | PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF33A | c.1965G>C p.Q655H (on ENST00000458705 / NM_006974.3; = p.Q656H on NM_006954.2) | Missense Mutation (SNP) | VAF 38/431 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); called by muse, mutect2
- ZNF831 | c.2889C>G p.S963R | Missense Mutation (SNP) | VAF 14/93 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- ZNF99 | c.937T>A p.Y313N | Missense Mutation (SNP) | VAF 22/428 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ARG2 | c.144C>T p.A48= | Silent (SNP) | VAF 21/286 reads (7%) | called by muse, mutect2
- CSMD3 | c.7957C>A p.R2653= (on ENST00000297405 / NM_001363185.1; = p.R2549= on NM_052900.3) | Silent (SNP) | VAF 101/358 reads (28%) | catalogued as COSV52140719, COSV52280497; called by muse, mutect2, varscan2
- DKKL1 | c.279C>T p.H93= | Silent (SNP) | VAF 6/141 reads (4%) | catalogued as rs1394053682; called by muse, mutect2
- DPRX | c.180G>T p.L60= | Silent (SNP) | VAF 16/150 reads (11%) | catalogued as COSV64949853; called by muse, mutect2
- FCGBP | c.1632C>T p.R544= | Silent (SNP) | VAF 6/83 reads (7%) | catalogued as rs1383146540; called by muse, mutect2
- IK | c.411A>G p.K137= | Silent (SNP) | VAF 26/149 reads (17%) | called by muse, mutect2, varscan2
- KCNK3 | c.648G>T p.T216= | Silent (SNP) | VAF 42/314 reads (13%) | called by muse, mutect2, varscan2
- KIF16B | c.1155G>C p.T385= | Silent (SNP) | VAF 33/208 reads (16%) | called by muse, mutect2, varscan2
- LHX8 | c.24G>A p.Q8= | Silent (SNP) | VAF 38/372 reads (10%) | called by muse, mutect2, varscan2
- MACO1 | c.252A>G p.A84= | Silent (SNP) | VAF 8/89 reads (9%) | called by muse, mutect2
- MME | c.288C>A p.V96= | Silent (SNP) | VAF 64/459 reads (14%) | catalogued as COSV64710177; called by muse, mutect2, varscan2
- MSLNL | c.232C>T p.L78= | Silent (SNP) | VAF 36/262 reads (14%) | called by muse, mutect2, varscan2
- OTOGL | c.2203A>C p.R735= (on ENST00000547103; = p.R726= on NM_173591.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 24/300 reads (8%) | called by muse, mutect2
- PCNX1 | c.1494A>G p.E498= | Silent (SNP) | VAF 22/332 reads (7%) | called by muse, mutect2
- PRR14L | c.1881C>T p.S627= | Silent (SNP) | VAF 33/302 reads (11%) | catalogued as rs1473087683; called by muse, mutect2, varscan2
- RTP5 | c.780C>A p.G260= | Silent (SNP) | VAF 20/130 reads (15%) | called by muse, mutect2, varscan2
- SBF1 | c.1941G>T p.L647= | Silent (SNP) | VAF 46/448 reads (10%) | called by muse, mutect2
- SCAF1 | c.1410G>C p.P470= | Silent (SNP) | VAF 5/38 reads (13%) | called by muse, mutect2
- SLAMF9 | c.33G>C p.L11= | Silent (SNP) | VAF 20/207 reads (10%) | called by muse, mutect2
- SMC6 | c.243G>A p.G81= | Silent (SNP) | VAF 27/187 reads (14%) | called by muse, mutect2, varscan2
- SNRPN | c.73C>A p.R25= | Silent (SNP) | VAF 19/218 reads (9%) | catalogued as rs780552612, COSV57596054; called by muse, mutect2
- SOWAHB | c.2022G>T p.L674= | Silent (SNP) | VAF 33/276 reads (12%) | called by muse, mutect2, varscan2
- TMEM249 | c.333C>T p.R111= | Silent (SNP) | VAF 100/388 reads (26%) | called by muse, mutect2, varscan2
- TMEM42 | c.33C>T p.A11= | Silent (SNP) | VAF 5/51 reads (10%) | catalogued as COSV56643764; called by muse, mutect2
- TTN | c.35097A>T p.P11699= (on ENST00000591111; = p.P10772= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 12/128 reads (9%) | called by muse, mutect2, varscan2
- AP2M1 | c.1173+42G>T | Intron (SNP) | VAF 52/434 reads (12%) | called by muse, varscan2
- AP2M1 | c.1173+43G>T | Intron (SNP) | VAF 50/432 reads (12%) | called by muse, varscan2
- CBWD2 | c.528+815C>A | Intron (SNP) | VAF 34/431 reads (8%) | called by muse, mutect2
- EPB41L1 | c.1669-2433G>A | Intron (SNP) | VAF 19/155 reads (12%) | called by muse, mutect2, varscan2
- ETNK2 | c.*14C>G | 3'UTR (SNP) | VAF 41/314 reads (13%) | called by muse, mutect2, varscan2
- EVX1 | chr7:27239412 A>G | 5'Flank (SNP) | VAF 21/145 reads (14%) | called by muse, mutect2, varscan2
- GABRA6 | c.-39C>A | 5'UTR (SNP) | VAF 12/328 reads (4%) | catalogued as rs1392799103; called by muse, mutect2
- HAND2-AS1 | n.512+1209G>A | Intron (SNP) | VAF 8/93 reads (9%) | called by muse, mutect2
- LEPROT | chr1:65420643 G>C | 5'Flank (SNP) | VAF 8/190 reads (4%) | called by muse, mutect2
- MAMLD1 | c.*578G>C | 3'UTR (SNP) | VAF 6/100 reads (6%) | called by muse, mutect2
- MASP1 | c.1304-5730A>G | Intron (SNP) | VAF 42/454 reads (9%) | called by muse, mutect2
- PEG3 | c.-186C>G | 5'UTR (SNP) | VAF 20/225 reads (9%) | called by muse, mutect2
- PPP2R2C | c.71-271A>G | Intron (SNP) | VAF 10/115 reads (9%) | catalogued as rs1371409974; called by muse, mutect2
- PRRC1 | c.*1887A>G | 3'UTR (SNP) | VAF 32/259 reads (12%) | called by muse, mutect2, varscan2
- PRSS21 | c.91+28G>T | Intron (SNP) | VAF 13/91 reads (14%) | catalogued as rs779705343; called by muse, mutect2, varscan2
- SLC6A2 | chr16:55705198 T>A | 3'Flank (SNP) | VAF 18/249 reads (7%) | called by muse, mutect2
- TMCO1 | c.*2493A>G | 3'UTR (SNP) | VAF 45/368 reads (12%) | called by muse, mutect2, varscan2
- TMPRSS3 | c.-18G>C | 5'UTR (SNP) | VAF 51/569 reads (9%) | called by muse, mutect2
- UBXN4 | c.83-583G>T | Intron (SNP) | VAF 11/191 reads (6%) | called by muse, mutect2
